Somatic mutation profile of tumor specimen TCGA-63-A5MU-01A (aliquot TCGA-63-A5MU-01A-11D-A26M-08) from TCGA case TCGA-63-A5MU, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbe15126-e1b1-45c3-8f75-889ff33e13c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MU-10A (Blood Derived Normal), aliquot TCGA-63-A5MU-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecfc01d0-3573-45ed-ae6a-fa17d57e63fe

The open-access MAF lists 239 somatic variants for this specimen: 182 protein-altering or splice-affecting, 53 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 53, Nonsense Mutation 25, Frame Shift Del 6, Intron 3, In Frame Del 2, Splice Region 2, Nonstop Mutation 2, Splice Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 57/72 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745846460, COSV99566723; called by muse, mutect2, varscan2
- ABCC11 | c.1295T>C p.F432S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100751179; called by muse, mutect2, varscan2
- ABI2 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 91/144 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99652309; called by muse, mutect2, varscan2
- ACP7 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100488626; called by muse, mutect2, varscan2
- ACSBG1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as rs745602145, COSV99357826; called by muse, mutect2, varscan2
- ACSL6 | c.1664G>T p.R555L (on ENST00000379240; = p.R580L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57303962, COSV99734756; called by muse, mutect2, varscan2
- ADGRL2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003335830, COSV54655876; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4254C>A p.D1418E | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV99784604; called by muse, mutect2, varscan2
- ANKRD52 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921644; called by muse, mutect2
- ARHGAP31 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 27/148 reads (18%) | catalogued as COSV99957796; called by muse, mutect2, varscan2
- ARID5B | c.566C>G p.S189W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99690534; called by muse, mutect2, varscan2
- ASAP1 | c.3223A>T p.I1075F | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100727947; called by muse, mutect2, varscan2
- ATP6V1G1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs754577497, COSV100928726; called by mutect2, varscan2
- ATP9A | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV58772701; called by muse, mutect2
- AURKC | c.565G>A p.V189M (on ENST00000302804 / NM_001015878.2; = p.V155M on NM_003160.3) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57137023; called by muse, mutect2, varscan2
- B4GALNT3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV99843659; called by muse, mutect2, varscan2
- BMP8B | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV100560406; called by muse, mutect2
- BRD4 | c.2209A>C p.K737Q | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99651484; called by muse, mutect2, varscan2
- BRDT | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 52/104 reads (50%) | catalogued as COSV100746604; called by muse, mutect2, varscan2
- C1orf216 | c.268A>C p.I90L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99231585; called by muse, mutect2, varscan2
- C8orf34 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV61375003, COSV61378967; called by muse, mutect2, varscan2
- CACNA1E | c.3848T>A p.V1283E | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100705559; called by muse, mutect2, varscan2
- CACNA2D1 | c.1973A>C p.Y658S (on ENST00000356253 / NM_001366867.1; = p.Y646S on NM_000722.4) | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV100667445; called by muse, mutect2, varscan2
- CACNG3 | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137248; called by muse, mutect2, varscan2
- CAPN7 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs758632330, COSV99513072; called by muse, mutect2, varscan2
- CBLL1 | c.182-1G>C p.X61_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99755981; called by muse, mutect2, varscan2
- CD68 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs1398747487, COSV99549262; called by muse, mutect2, varscan2
- CFAP46 | c.7957C>A p.P2653T | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs902421120, COSV99585641; called by muse, mutect2, varscan2
- CHMP3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.227); catalogued as rs759236870, COSV55688060; called by muse, mutect2, varscan2
- CIP2A | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99843195; called by muse, mutect2, varscan2
- CNKSR2 | c.2742G>C p.R914S | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV101073341; called by muse, mutect2, varscan2
- COL24A1 | c.4178G>C p.G1393A | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65310167; called by muse, mutect2, varscan2
- CRACR2A | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377375003, COSV99365545; called by muse, mutect2, varscan2
- CRTAM | c.497del p.T166Sfs*19 | Frame Shift Del (DEL) | VAF 41/61 reads (67%) | catalogued as COSV57072095; called by mutect2, pindel, varscan2
- CSMD3 | c.4624G>A p.D1542N (on ENST00000297405 / NM_001363185.1; = p.D1438N on NM_052900.3) | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV52349455; called by muse, mutect2, varscan2
- CYLD | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV100282782; called by muse, mutect2, varscan2
- DACH2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV100913987; called by muse, mutect2, varscan2
- DAP3 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 14/153 reads (9%) | catalogued as COSV100546674; called by muse, mutect2
- DCTN1 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62620969; called by muse, mutect2, varscan2
- DDI2 | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100197915; called by muse, mutect2, varscan2
- DMD | c.10033C>G p.R3345G | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001666, COSV100629543; called by muse, mutect2, varscan2
- DNAH2 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 32/42 reads (76%) | catalogued as COSV99318615; called by muse, mutect2, varscan2
- DNAH8 | c.12791G>A p.R4264K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100543818, COSV100544619; called by muse, mutect2, varscan2
- DOCK2 | c.4291A>G p.I1431V | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV99915765; called by muse, mutect2, varscan2
- DPYS | c.1418A>T p.Y473F | Missense Mutation (SNP) | VAF 414/576 reads (72%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100680188; called by muse, mutect2, varscan2
- DRGX | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100938396; called by muse, mutect2, varscan2
- EFHC2 | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV100638065; called by muse, mutect2, varscan2
- EMSY | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as rs1026688873, COSV100596100; called by muse, mutect2, varscan2
- EPPK1 | c.1878C>G p.I626M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101599967, COSV73262260; called by muse, mutect2, varscan2
- FAM135B | c.3134C>A p.S1045* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV52760750; called by muse, mutect2, varscan2
- FANCL | c.586T>C p.S196P | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as COSV99287984; called by muse, mutect2, varscan2
- FANCM | c.1708C>G p.L570V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99951719; called by muse, mutect2, varscan2
- FBXL18 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1368203767, COSV101212126; called by muse, mutect2, varscan2
- FCGR3A | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100914617, COSV100914723; called by muse, mutect2, varscan2
- FHIT | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59282910, COSV59285524; called by muse, mutect2, varscan2
- FNIP1 | c.1900C>G p.Q634E | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.107); catalogued as COSV100330618; called by muse, mutect2, varscan2
- FOLR2 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 384/417 reads (92%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV99995588; called by muse, mutect2, varscan2
- GCNA | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV101032727; called by muse, mutect2, varscan2
- GFRA1 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as COSV100816222, COSV62610299; called by muse, mutect2, varscan2
- GLYATL1 | c.442A>G p.K148E (on ENST00000317391 / NM_001354699.1; = p.K179E on NM_080661.4) | Missense Mutation (SNP) | VAF 94/106 reads (89%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.989); catalogued as COSV100265583; called by muse, mutect2, varscan2
- GPRASP1 | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64356379; called by muse, mutect2, varscan2
- HMMR | c.1672G>T p.E558* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100701058; called by muse, mutect2, varscan2
- IFNA7 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99497617; called by muse, mutect2, varscan2
- IGSF1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs761258246, COSV100812359; called by muse, mutect2, varscan2
- IKZF1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV58785402; called by muse, mutect2, varscan2
- ITGA4 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 107/178 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99276854; called by muse, mutect2, varscan2
- JADE3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99510375; called by muse, mutect2, varscan2
- KCNIP4 | c.272A>T p.Y91F | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100749757; called by muse, mutect2, varscan2
- KCNJ3 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 84/127 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54544929, COSV99716544; called by muse, mutect2, varscan2
- KCNJ4 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100341106, COSV100341516; called by muse, mutect2, varscan2
- KCNU1 | c.3448T>G p.*1150Eext*21 | Nonstop Mutation (SNP) | VAF 18/239 reads (8%) | catalogued as COSV101299444; called by muse, mutect2
- KIRREL2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99384492; called by mutect2, varscan2
- KMT2D | c.4367G>T p.C1456F | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56411164, COSV99986120; called by muse, mutect2, varscan2
- KPNA3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as rs536858890, COSV99904404; called by muse, mutect2, varscan2
- KRT82 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV99233904; called by muse, mutect2, varscan2
- LUC7L3 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as COSV53589912; called by muse, mutect2, varscan2
- LY75 | c.2666C>G p.S889* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99717096; called by muse, mutect2, varscan2
- MNX1 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV53318101, COSV99429836; called by muse, mutect2, varscan2
- MUC20 | c.1817C>G p.P606R | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs776837792, COSV100291536; called by muse, mutect2, varscan2
- MYO3B | c.3422C>T p.T1141M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs370443836; called by muse, mutect2, varscan2
- MYOC | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 32/112 reads (29%) | catalogued as rs573459235, COSV99231754; called by muse, mutect2, varscan2
- NPC1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 55/114 reads (48%) | catalogued as COSV99342022; called by muse, mutect2, varscan2
- NR4A2 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100277406; called by muse, mutect2, varscan2
- NR5A2 | c.1265C>A p.A422D (on ENST00000367362 / NM_205860.3; = p.A376D on NM_003822.5) | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV99371735; called by muse, mutect2, varscan2
- NTNG1 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV99639714; called by muse, mutect2, varscan2
- OMD | c.337A>C p.N113H | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490306846, COSV100979094; called by muse, mutect2, varscan2
- OR10J5 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.537); catalogued as rs1230156863, COSV100604849; called by muse, mutect2, varscan2
- OR14A16 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV100713876, COSV62926077; called by muse, mutect2, varscan2
- OR2M7 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 67/552 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100522718; called by muse, mutect2, varscan2
- OR2T1 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV100822358; called by muse, mutect2, varscan2
- OR2T11 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781660238, COSV100424982; called by muse, mutect2, varscan2
- OR5T2 | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 146/168 reads (87%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV100507098; called by muse, mutect2, varscan2
- OR9G1 | c.409A>T p.I137L | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100380584; called by muse, mutect2
- PAK6 | c.1657A>C p.K553Q | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.903); catalogued as COSV99545117; called by muse, mutect2
- PARP2 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV99162455, COSV99163067; called by muse, mutect2, varscan2
- PCDH10 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as rs1343075994, COSV99994604; called by muse, mutect2, varscan2
- PCDH15 | c.5027C>A p.T1676N | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs1362820875, COSV100228168; called by muse, mutect2, varscan2
- PCDHAC1 | c.2690T>G p.L897W | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99163315; called by muse, mutect2, varscan2
- PCDHB11 | c.1629C>G p.S543R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100697197; called by muse, varscan2
- PCDHB5 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs140842033; called by muse, mutect2, varscan2
- PDE11A | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs565089042, COSV99615311; called by muse, mutect2, varscan2
- PDE1C | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.103); catalogued as rs267601486, COSV58516968, COSV58527985; called by muse, mutect2, varscan2
- PEAR1 | c.27_29del p.L11del | In Frame Del (DEL) | VAF 28/165 reads (17%) | catalogued as rs373675759; called by mutect2, pindel, varscan2
- PEG10 | c.172G>A p.D58N (on ENST00000482108 / NM_001040152.2; = p.D92N on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101509981; called by muse, mutect2, varscan2
- PFKFB3 | c.1423C>G p.R475G | Missense Mutation (SNP) | VAF 20/105 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100432397; called by muse, mutect2, varscan2
- PGLYRP1 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99151534; called by muse, mutect2, varscan2
- PHKB | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100068648; called by muse, mutect2, varscan2
- PI4K2B | c.1415A>T p.N472I | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99335661; called by muse, mutect2, varscan2
- PKD1L1 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs777027335, COSV99221506; called by muse, varscan2
- PNMA5 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 102/113 reads (90%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.839); catalogued as COSV100721720, COSV62626402; called by muse, mutect2, varscan2
- POF1B | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV99427518; called by muse, mutect2, varscan2
- POTEE | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 106/412 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as rs777410341, COSV100389092; called by muse, mutect2, varscan2
- POTEF | c.1124del p.P375Qfs*5 | Frame Shift Del (DEL) | VAF 28/58 reads (48%) | catalogued as COSV62541349; called by mutect2, pindel*, varscan2
- PPP1R15A | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV52338863, COSV99566279; called by muse, mutect2, varscan2
- PPP6C | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101001267, COSV65207059; called by muse, varscan2
- PPT2 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs957783092, COSV99278697; called by muse, mutect2, varscan2
- RALYL | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768986699, COSV101569478; called by muse, mutect2, varscan2
- RASSF4 | c.698T>G p.L233* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100437283; called by muse, mutect2, varscan2
- RBM6 | c.2342A>T p.Q781L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99805999; called by muse, mutect2, varscan2
- RELN | c.7933C>A p.H2645N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV100634986, COSV58985708, COSV99067080; called by muse, mutect2, varscan2
- RGS18 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376472982; called by muse, mutect2, varscan2
- RPGRIP1L | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100046876; called by muse, mutect2, varscan2
- RPS6KA3 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101084689; called by muse, mutect2, varscan2
- RXFP2 | c.1174T>A p.Y392N | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100034669; called by muse, mutect2, varscan2
- RYR2 | c.4726A>T p.K1576* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100773123; called by muse, mutect2, varscan2
- RYR3 | c.3157C>A p.P1053T | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV101214777; called by muse, mutect2, varscan2
- RYR3 | c.3158C>A p.P1053Q | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101214779; called by muse, mutect2, varscan2
- SF3B1 | c.2708A>G p.Q903R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136056, COSV59210642; called by muse, mutect2, varscan2
- SHD | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV100010535; called by muse, mutect2, varscan2
- SLC12A5 | c.3046C>A p.P1016T (on ENST00000454036 / NM_001134771.2; = p.P993T on NM_020708.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV99276090; called by muse, mutect2
- SLC28A1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV54477264; called by muse, mutect2, varscan2
- SLC2A13 | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99787215; called by muse, mutect2, varscan2
- SLC2A13 | c.1318A>T p.S440C | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99787225; called by muse, mutect2, varscan2
- SLC35F4 | c.1321G>A p.A441T (on ENST00000339762 / NM_001352015.2; = p.A405T on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334283; called by muse, mutect2, varscan2
- SLC4A7 | c.3336T>C p.V1112= | Splice Region (SNP) | VAF 57/116 reads (49%) | catalogued as rs1389438836, COSV99840412; called by muse, mutect2
- SLC9A4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99763605; called by muse, mutect2, varscan2
- SLCO5A1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs548263300, COSV52655083; called by muse, mutect2, varscan2
- SLIT2 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99887617; called by muse, mutect2, varscan2
- SMG1 | c.10399C>G p.Q3467E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.9); catalogued as COSV101246919; called by muse, mutect2
- SOX5 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.035); catalogued as COSV100508411; called by muse, mutect2
- SPATA31D1 | c.1370C>G p.S457* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100783028, COSV100783082; called by muse, mutect2, varscan2
- SPRYD7 | c.307A>T p.R103* | Nonsense Mutation (SNP) | VAF 45/67 reads (67%) | catalogued as COSV100709892; called by muse, mutect2, varscan2
- SRI | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 40/250 reads (16%) | catalogued as COSV99719937; called by muse, mutect2, varscan2
- SSX7 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 185/207 reads (89%) | catalogued as COSV99994035; called by muse, mutect2, varscan2
- SUPT6H | c.3983G>A p.R1328K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100112815; called by muse, mutect2, varscan2
- SVEP1 | c.5809T>C p.L1937= | Splice Region (SNP) | VAF 40/63 reads (63%) | catalogued as COSV99929912; called by muse, mutect2, varscan2
- TBC1D7 | c.880T>C p.*294Rext*26 | Nonstop Mutation (SNP) | VAF 60/70 reads (86%) | catalogued as COSV100568736; called by muse, mutect2, varscan2
- TBCK | c.2542G>T p.V848L (on ENST00000273980 / NM_001163436.4; = p.V785L on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV56752931, COSV56753758; called by muse, mutect2, varscan2
- TMEM106B | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV101188890; called by muse, mutect2, varscan2
- TOMM34 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100861938; called by muse, mutect2, varscan2
- TRAK2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | catalogued as rs755203013, COSV60271352, COSV60273975; called by muse, mutect2, varscan2
- TRDMT1 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | catalogued as COSV100004168; called by muse, mutect2
- TRIM39 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV100935932; called by muse, mutect2, varscan2
- TTN | c.31591C>T p.P10531S (on ENST00000591111; = p.P9604S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | PolyPhen benign (0.109); catalogued as rs368286625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBA6 | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100451932; called by muse, mutect2, varscan2
- UBR5 | c.6071G>T p.R2024L | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV55280637, COSV99642495; called by muse, mutect2, varscan2
- USP32 | c.1979del p.R660Pfs*31 | Frame Shift Del (DEL) | VAF 62/101 reads (61%) | catalogued as COSV100342582; called by mutect2, varscan2
- USP51 | c.1627A>T p.I543L | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV101540704; called by muse, mutect2, varscan2
- UTRN | c.8941G>A p.G2981R | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100837945; called by muse, mutect2, varscan2
- WDFY3 | c.8545G>C p.E2849Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885876; called by muse, mutect2, varscan2
- WDSUB1 | c.38A>G p.D13G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100701908; called by muse, mutect2, varscan2
- WNK2 | c.1118A>T p.Y373F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99944856; called by muse, mutect2, varscan2
- ZBED9 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 79/94 reads (84%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV101509406; called by muse, mutect2, varscan2
- ZIC1 | c.991C>G p.P331A | Missense Mutation (SNP) | VAF 98/139 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99292498; called by muse, mutect2, varscan2
- ZIM3 | c.797G>T p.C266F | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV99518748; called by muse, mutect2, varscan2
- ZNF33B | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.404); catalogued as rs1415500833, COSV100847798, COSV63941819; called by muse, mutect2, varscan2
- ZNF430 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as COSV99842068; called by muse, mutect2, varscan2
- ZNF48 | c.1540C>A p.L514M | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV100198236; called by muse, mutect2, varscan2
- ZNF641 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99973706; called by muse, mutect2, varscan2
- ZNF654 | c.2675C>G p.S892* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100525632; called by muse, mutect2, varscan2
- ZNF98 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as rs770210991, COSV99078220; called by mutect2, varscan2
- ZNHIT1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 56/174 reads (32%) | catalogued as rs773927841, COSV59313342; called by muse, mutect2, varscan2
- C5orf22 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- CDKN2A | c.170_174del p.A57Gfs*61 | Frame Shift Del (DEL) | VAF 11/13 reads (85%) | called by mutect2, varscan2*
- IGKV1-17 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- KRT5 | c.816dup p.V273Cfs*22 | Frame Shift Ins (INS) | VAF 44/206 reads (21%) | called by mutect2, pindel, varscan2
- LRP1B | c.2983del p.D995Tfs*184 | Frame Shift Del (DEL) | VAF 39/86 reads (45%) | called by mutect2, pindel, varscan2
- NOVA2 | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- ROCK2 | c.4115del p.N1372Tfs*22 | Frame Shift Del (DEL) | VAF 47/289 reads (16%) | called by mutect2, pindel, varscan2
- TDRD6 | c.4416_4442del p.D1472_S1480del | In Frame Del (DEL) | VAF 65/98 reads (66%) | called by mutect2, pindel, varscan2
- TRGC1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- AQR | c.1071A>T p.A357= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV99334787; called by muse, mutect2, varscan2
- AREL1 | c.1155A>T p.T385= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100707657; called by muse, mutect2, varscan2
- BBS12 | c.2016G>T p.A672= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV100044844, COSV58561714; called by muse, mutect2, varscan2
- BRINP1 | c.1878T>G p.P626= | Silent (SNP) | VAF 74/144 reads (51%) | catalogued as COSV99776462, COSV99777042; called by muse, mutect2, varscan2
- C19orf57 | c.882T>A p.P294= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100694867; called by muse, mutect2, varscan2
- CD163L1 | c.2721C>G p.S907= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100550702, COSV100550811; called by muse, mutect2, varscan2
- COLEC10 | c.570T>A p.A190= | Silent (SNP) | VAF 76/105 reads (72%) | catalogued as COSV100250928; called by muse, mutect2, varscan2
- CTNNA2 | c.1941T>C p.Y647= | Silent (SNP) | VAF 45/69 reads (65%) | catalogued as COSV100562149; called by muse, mutect2, varscan2
- CTNND2 | c.2766C>T p.D922= | Silent (SNP) | VAF 68/104 reads (65%) | catalogued as rs746806956, COSV58930045; called by muse, mutect2, varscan2
- CTNND2 | c.1479C>A p.A493= | Silent (SNP) | VAF 66/98 reads (67%) | catalogued as rs752135363, COSV58891468; called by muse, mutect2, varscan2
- DCLK3 | c.846G>T p.A282= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV101374152, COSV69363189; called by muse, mutect2, varscan2
- DOLPP1 | c.24G>T p.S8= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100588477; called by muse, mutect2, varscan2
- DUSP21 | c.423C>T p.P141= | Silent (SNP) | VAF 54/59 reads (92%) | catalogued as COSV100173678; called by muse, mutect2, varscan2
- FAT4 | c.2466C>G p.L822= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as COSV101272348, COSV67892817; called by muse, mutect2, varscan2
- FBXL7 | c.459C>G p.L153= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100311024; called by muse, mutect2, varscan2
- FRMD4A | c.2625G>T p.A875= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100662558; called by muse, varscan2
- GALNT16 | c.858C>A p.P286= | Silent (SNP) | VAF 58/85 reads (68%) | catalogued as COSV100546211; called by muse, mutect2, varscan2
- GPR1 | c.480C>T p.F160= | Silent (SNP) | VAF 75/116 reads (65%) | catalogued as COSV101329863, COSV101329873; called by muse, mutect2, varscan2
- IFT172 | c.1708C>T p.L570= | Silent (SNP) | VAF 58/486 reads (12%) | catalogued as COSV99563438; called by muse, mutect2, varscan2
- LILRA1 | c.525T>C p.H175= | Silent (SNP) | VAF 75/147 reads (51%) | catalogued as rs1271042427, COSV52186260, COSV99252244; called by muse, mutect2, varscan2
- LILRB2 | c.654C>A p.V218= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV100079693; called by muse, mutect2, varscan2
- LIPI | c.507A>G p.A169= | Silent (SNP) | VAF 53/226 reads (23%) | catalogued as COSV100754039; called by muse, mutect2, varscan2
- LRRIQ1 | c.426C>T p.D142= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV101277744; called by muse, mutect2, varscan2
- MAGEF1 | c.852C>T p.A284= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs754358614, COSV100511049; called by muse, mutect2, varscan2
- MAP2K6 | c.291G>C p.L97= | Silent (SNP) | VAF 8/155 reads (5%) | catalogued as COSV100765148; called by muse, mutect2
- MED12 | c.2637C>T p.L879= | Silent (SNP) | VAF 5/110 reads (5%) | catalogued as COSV100380144; called by muse, mutect2
- NECAP2 | c.36C>T p.V12= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV59188757, COSV59188773; called by muse, mutect2, varscan2
- NLGN1 | c.243T>G p.L81= | Silent (SNP) | VAF 149/211 reads (71%) | catalogued as COSV100850267; called by muse, mutect2, varscan2
- OR10K2 | c.324C>A p.G108= | Silent (SNP) | VAF 130/181 reads (72%) | catalogued as COSV100149676; called by muse, mutect2, varscan2
- OR2M3 | c.465T>C p.D155= | Silent (SNP) | VAF 68/406 reads (17%) | catalogued as COSV71759043; called by muse, mutect2, varscan2
- OR4C46 | c.888C>A p.I296= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as rs773942533, COSV100061023; called by muse, mutect2, varscan2
- PALD1 | c.1758C>T p.S586= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs778748768, COSV99698697; called by muse, mutect2, varscan2
- PAPSS1 | c.1318C>T p.L440= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs760111620, COSV54489013, COSV99492470; called by muse, mutect2, varscan2
- PHACTR2 | c.927C>T p.V309= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99992431; called by muse, mutect2, varscan2
- PLCD4 | c.738G>A p.L246= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV101335833; called by muse, mutect2, varscan2
- POU6F2 | c.1953T>A p.V651= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV101302882; called by muse, mutect2, varscan2
- PRDM9 | c.546C>T p.S182= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as COSV57012437; called by muse, mutect2, varscan2
- RPGRIP1L | c.267G>A p.K89= | Silent (SNP) | VAF 40/205 reads (20%) | catalogued as rs1434968352, COSV50904696; called by muse, mutect2, varscan2
- RPL6 | c.855A>G p.K285= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1171333470, COSV99176190; called by muse, mutect2, varscan2
- RTN1 | c.1908C>T p.I636= | Silent (SNP) | VAF 102/172 reads (59%) | catalogued as COSV99956976; called by muse, mutect2, varscan2
- SEMA6A | c.2883C>T p.P961= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1308246031, COSV56710211; called by muse, mutect2, varscan2
- SLC16A3 | c.1284G>A p.K428= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100012727; called by muse, mutect2, varscan2
- SLC4A1 | c.1461C>A p.I487= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV52262220, COSV99293717; called by mutect2, varscan2
- SLITRK2 | c.1428G>A p.L476= | Silent (SNP) | VAF 237/264 reads (90%) | catalogued as COSV100158268; called by muse, mutect2, varscan2
- SNTG1 | c.114C>T p.I38= | Silent (SNP) | VAF 43/247 reads (17%) | catalogued as COSV99386403; called by muse, mutect2, varscan2
- SPATA31D1 | c.2109C>A p.P703= | Silent (SNP) | VAF 48/77 reads (62%) | catalogued as COSV100782442, COSV100783083; called by muse, mutect2, varscan2
- SYNE1 | c.5853G>A p.T1951= (on ENST00000367255 / NM_182961.4; = p.T1958= on NM_033071.3) | Silent (SNP) | VAF 113/131 reads (86%) | catalogued as rs747430966, COSV99580576; called by muse, mutect2, varscan2
- TBL2 | c.534C>T p.A178= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99979767; called by muse, mutect2, varscan2
- UNC79 | c.7422C>T p.H2474= (on ENST00000393151 / NM_001346218.2; = p.H2297= on NM_020818.5) | Silent (SNP) | VAF 11/202 reads (5%) | catalogued as rs753339945, COSV99829957; called by muse, mutect2
- ZC3H7B | c.267C>A p.A89= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV100687829; called by muse, varscan2
- ZNF438 | c.621G>A p.V207= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV100062858; called by muse, mutect2, varscan2
- ZNF718 | c.1125C>T p.A375= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV101210294; called by muse, mutect2, varscan2
- ZNF768 | c.1611G>A p.A537= | Silent (SNP) | VAF 41/56 reads (73%) | catalogued as rs1310731267, COSV100776367; called by muse, mutect2, varscan2
- CXCL17 | c.-1G>A | 5'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as rs149050070; called by muse, mutect2, varscan2
- IFT43 | c.296-5662C>T | Intron (SNP) | VAF 45/86 reads (52%) | catalogued as rs955489756, COSV53136847; called by muse, mutect2
- MACF1 | c.15832-9922_15832-9905del | Intron (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- MRC1 | c.917-103G>A | Intron (SNP) | VAF 114/378 reads (30%) | called by muse, mutect2, varscan2
